FM case AD3193 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/293513af-cc98-4f12-861a-bc306266eb00

Female, 73.7 years: Lobular carcinoma, NOS (ICD-O-3 8520/3) of the breast; metastasis biopsied or resected from the bone marrow. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
